Gene-level copy-number profile of tumor specimen TCGA-VS-A8EH-01A from TCGA case TCGA-VS-A8EH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 56.8 years (20,728 days).
Specimen TCGA-VS-A8EH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.9eb3a0d7-db6a-4927-9c85-6194086f4fb7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A8EH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bba361f0-d5fd-43e2-a436-2772bd6ca7d9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,264; copy number 2: 13,831; copy number 3: 27,991; copy number 4: 11,581; copy number 5: 2,995; copy number 6: 647; copy number 7: 40; copy number 8: 1,121; copy number 9: 322; copy number 11: 7; copy number 12: 2; copy number 13: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A8EH-01A-11D-A36I-01): tumor purity 0.72, ploidy 3.04, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,504 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:149,587,196–150,047,447, 1 gene, copy number 7 (within-gene range 2–7): MMADHC-DT.
- chr2:149,745,648–150,356,460, 4 genes, copy number 7: LINC01931, AC016682.1, LINC01818, LINC01817.
- chr3:123,897,305–198,222,513, 1,360 genes, copy number 8–9 (broad region; genes not listed).
- chr9:113,349,541–118,072,314, 63 genes, copy number 8–13 (within-gene range 5–13) (broad region; genes not listed).
- chr11:80,653,429–81,556,425, 7 genes, copy number 7: ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25.
- chr11:82,603,529–83,423,516, 31 genes, copy number 9: AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2.
- chr11:83,643,602–83,725,390, 1 gene, copy number 9 (within-gene range 1–9): DLG2-AS2.
- chr13:23,888,842–23,897,502, 2 genes, copy number 12: PCOTH, C1QTNF9B.
- chr21:36,156,782–36,294,274, 1 gene, copy number 7 (within-gene range 2–7): DOP1B.
- chr21:36,295,173–37,268,497, 34 genes, copy number 7–11: SRSF9P1, AP000692.2, MORC3, AP000692.1, CHAF1B, ATP5MFP1, AP000695.1, AP000695.2, CLDN14, AP000695.3, PSMD4P1, AP000696.2, AP000696.3, AP000696.1, AP000697.1, SIM2, HLCS, HLCS-IT1, RNA5SP491, DPRXP5, AP000704.1, Y_RNA, MRPL20P1, RIPPLY3, RNU6-696P, PIGP, TTC3, AP001429.1, TTC3-AS1, DSCR9, RN7SL678P, AP001432.1, VPS26C, AP001412.1.

Autosomal genes at a single copy (total copy number 1): 1,264. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
